CGCI case HTMCP-01-02-00017 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d0a141da-0dcf-4241-a374-9e0cff4b035a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Dead; Days to death: 195 days.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 55.3 years (20,185 days); Year of diagnosis: 1999; Ann Arbor clinical stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 195 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Cervical lymph nodes; Sites of involvement: Cerebrospinal fluid.
   Pathology details: Lymph node involved site: Cervical, NOS.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Axillary; Tumor largest dimension diameter: 21 cm.
   Pathology details: Lymph node involved site: Inguinal.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (4 entries)
- Days to follow up: 0 days; ECOG performance status: 1.
- Days to follow up: 195 days; Disease response: With Tumor.
- Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 10.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL2 other: Abnormal, NOS.
- BCL6 (IHC): Negative; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Positive; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- TP53: Positive; Specialized molecular test: P53 > 20%.
- Lactate Dehydrogenase 202 [Blood test normal range upper: 226].
- Epstein-Barr Virus: Negative.
- Epstein-Barr Virus (ISH): Equivocal.

Other clinical attributes
- Day 0: Comorbidities: Herpes.
- Day 0: Weight: 76.1 kg; Height: 184.2 cm; BMI: 22.4; CD4 count: 133; Haart treatment indicator: No; HIV viral load: 102618.
- Day 0: Comorbidities: Hepatitis C Infection.
- Day 0: Comorbidities: Hepatitis B Infection.
- Day 10: Comorbidities: HIV/AIDS.
- Day 10: Risk factors: HIV/AIDS.
- Day 195: Nadir CD4 count: 133.

Biospecimens (3 samples)
- Sample HTMCP-01-02-00017-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-02-00017-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-02-00017-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- History of disease: Haart therapy prior to diagnosis: No; Haart therapy at diagnosis: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Other Extranodal Site.
- Primary pathology: Extranodal involvment other: Cerebrospinal Fluid; Extranodal site involvement: 1; Days from index date to tumor sample procurement: 4.
- Tests performed: LDH level: 202.
- Tests performed, Genetic testing results, Genetic testing result: Immunophenotypic analysis tested: P53 >20%.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: BCL2.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_GDC_Submission001_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-01-02-00017-10A-01D-124:
- % tumour top: 0
- % tumour bottom: 0
